Gene-level copy-number profile of tumor specimen TCGA-B0-4710-01A from TCGA case TCGA-B0-4710, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.0 years (27,396 days).
Specimen TCGA-B0-4710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.42742aaf-2dea-480a-b944-d933e2e11986.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4710-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ed220a7-e439-47f7-96e7-2fa10de45f1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 7,670; copy number 2: 52,119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B0-4710-01A-01D-1499-01): tumor purity 0.53, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:67,225,464–70,518,064, 31 genes: MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
